Somatic mutation profile of tumor specimen TCGA-V4-A9EJ-01A (aliquot TCGA-V4-A9EJ-01A-11D-A39W-08) from TCGA case TCGA-V4-A9EJ, project TCGA-UVM (Uveal Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIB; Age at diagnosis: 38.2 years (13,958 days).
Specimen TCGA-V4-A9EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee3c1bd5-4faf-42ce-b885-8d14d615e9f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9EJ-10A (Blood Derived Normal), aliquot TCGA-V4-A9EJ-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7f02699-2efc-4f8d-934a-625cd18e5746

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 15, Silent 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1874G>A p.R625H | Missense Mutation (SNP) | VAF 18/44 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519961, COSV59205431, COSV59206122, COSV59206364; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRG4 | c.7777-1G>T p.X2593_splice | Splice Site (SNP) | VAF 43/45 reads (96%) | catalogued as COSV54959562, COSV54961749; called by muse, mutect2, varscan2
- ARNT2 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1211454281, COSV100308950; called by muse, mutect2, varscan2
- PKHD1L1 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751058194; called by muse, mutect2, varscan2
- TNFSF14 | c.649G>A p.V217I | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs202048657, COSV55591291; called by muse, mutect2, varscan2
- ADAMTS18 | c.326A>C p.H109P | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR11H1 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); called by mutect2, varscan2
- PDE8B | c.377G>A p.R126K | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PHLDB1 | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- PHLDB1 | c.1649C>T p.A550V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- PIP4K2A | c.217A>C p.K73Q | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RASGRF2 | c.1865A>G p.D622G | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- SEL1L3 | c.784G>A p.G262S | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TKFC | c.869G>A p.G290D | Missense Mutation (SNP) | VAF 52/110 reads (47%) | SIFT tolerated (0.53); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF599 | c.931T>G p.F311V | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- FAM71D | c.594C>T p.D198= | Silent (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- GPR68 | c.75G>A p.P25= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs199863841; called by muse, mutect2, varscan2
- MUC2 | c.2019C>A p.T673= | Silent (SNP) | VAF 17/54 reads (31%) | called by muse, mutect2, varscan2
- NAA38 | c.330T>C p.V110= (on ENST00000575771 / NM_001320925.2; = p.V158= on NM_032356.5) | Silent (SNP) | VAF 20/58 reads (34%) | called by muse, mutect2, varscan2
